Somatic mutation profile of tumor specimen TCGA-CV-7406-01A (aliquot TCGA-CV-7406-01A-11D-2078-08) from TCGA case TCGA-CV-7406, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: GX; Age at diagnosis: 50.0 years (18,250 days).
Specimen TCGA-CV-7406-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6c87d4c-c36c-468e-bbc0-17d130ca9f8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7406-10A (Blood Derived Normal), aliquot TCGA-CV-7406-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6069395d-7f1e-432a-a5a1-d74b9291c446

The open-access MAF lists 213 somatic variants for this specimen: 152 protein-altering or splice-affecting, 56 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 56, Nonsense Mutation 10, Frame Shift Del 8, Splice Site 3, Splice Region 3, 3'Flank 1, In Frame Del 1, Intron 1, RNA 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 8/77 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AC011448.1 | c.132C>G p.I44M | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.033); catalogued as COSV99388942; called by muse, mutect2, varscan2
- ADAMTS20 | c.1621C>A p.R541S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.392); catalogued as COSV101239019, COSV67130583; called by muse, mutect2, varscan2
- ADCY1 | c.3283G>A p.V1095I | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.006); catalogued as rs763670732, COSV52041109; called by muse, mutect2, varscan2
- AICDA | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV57563598; called by muse, mutect2, varscan2
- ALOXE3 | c.1897A>G p.N633D | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.477); catalogued as COSV100559630; called by muse, mutect2, varscan2
- ANKRD34B | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100103399; called by muse, mutect2, varscan2
- ARHGAP36 | c.1482T>A p.D494E | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99357346; called by muse, mutect2
- ARMC8 | c.726G>T p.K242N (on ENST00000469044 / NM_001363941.2; = p.K228N on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.096); catalogued as COSV100627531, COSV100627709; called by muse, mutect2, varscan2
- ASXL3 | c.5485A>C p.K1829Q | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); catalogued as COSV99323764; called by muse, mutect2, varscan2
- B3GALNT2 | c.733G>T p.D245Y | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs751860328, COSV100010157; called by muse, mutect2, varscan2
- BSN | c.7802G>A p.R2601Q | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs754421677, COSV99607520; called by muse, mutect2, varscan2
- CABIN1 | c.3464C>T p.S1155L | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV54080590, COSV99572802; called by muse, mutect2, varscan2
- CAMTA2 | c.51G>T p.K17N | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV100742001; called by muse, mutect2, varscan2
- CCBE1 | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs755658403, COSV101232786; called by muse, mutect2, varscan2
- CCR3 | c.859G>C p.E287Q | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as COSV100656360, COSV62462261; called by muse, mutect2, varscan2
- CD44 | c.1117C>T p.H373Y | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.133); catalogued as COSV99555494; called by muse, mutect2, varscan2
- CFAP61 | c.2359C>G p.Q787E | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV99843629; called by muse, mutect2
- CLOCK | c.1562G>T p.G521V | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV100011638; called by muse, mutect2, varscan2
- COBL | c.2668G>A p.G890S | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as rs374030012; called by muse, mutect2, varscan2
- COL14A1 | c.4873G>A p.E1625K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs866412093, COSV99918290; called by muse, mutect2, varscan2
- COPA | c.360G>A p.W120* | Nonsense Mutation (SNP) | VAF 25/78 reads (32%) | catalogued as COSV99614855; called by muse, mutect2, varscan2
- CP | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.168); catalogued as COSV99223795; called by muse, mutect2, varscan2
- CSMD3 | c.4048G>A p.E1350K (on ENST00000297405 / NM_001363185.1; = p.E1246K on NM_052900.3) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.542); catalogued as rs369452274; called by muse, mutect2, varscan2
- CYB5R2 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs149733078; called by muse, mutect2, varscan2
- DHX9 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 63/232 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100841270; called by muse, mutect2, varscan2
- DLGAP1 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as rs779305058, COSV59780431; called by mutect2, varscan2
- DNAH9 | c.8185G>C p.D2729H | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99304565; called by muse, mutect2, varscan2
- DOCK3 | c.5321G>A p.R1774H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs751113149, COSV99809741; called by muse, mutect2, varscan2
- DRICH1 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV58503463; called by muse, mutect2, varscan2
- EGR1 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV53519662, COSV99525331; called by muse, mutect2, varscan2
- ELF4 | c.731C>G p.S244C | Missense Mutation (SNP) | VAF 63/104 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100257213; called by muse, mutect2, varscan2
- ELP5 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100020922; called by muse, mutect2
- ENC1 | c.721C>G p.L241V | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); catalogued as COSV100187954, COSV56629619; called by muse, mutect2, varscan2
- ENDOD1 | c.303C>T p.I101= | Splice Region (SNP) | VAF 5/27 reads (19%) | catalogued as rs899281622, COSV99566396; called by muse, mutect2, varscan2
- EPHA1 | c.2511G>C p.K837N | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV99313574; called by muse, mutect2, varscan2
- FAM135A | c.587C>T p.P196L (on ENST00000370479 / NM_001351599.1; = p.P153L on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV99525375; called by muse, mutect2, varscan2
- FECH | c.1060C>G p.Q354E | Missense Mutation (SNP) | VAF 60/309 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.018); catalogued as CD1010124, COSV50492181; called by muse, mutect2, varscan2
- FEZF1 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.297); catalogued as rs777966600, COSV58659358; called by muse, mutect2, varscan2
- FLACC1 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99629918; called by muse, mutect2, varscan2
- FLNC | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as rs771092335, COSV57955747; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNC | c.5451_5453del p.N1817del | In Frame Del (DEL) | VAF 26/96 reads (27%) | catalogued as rs1312829675; called by pindel, varscan2
- GBP1 | c.255C>A p.H85Q | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100976226; called by muse, varscan2
- GBP1 | c.254A>C p.H85P | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100976228; called by muse, varscan2
- GINS1 | c.397G>A p.G133S | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs1555832620, COSV52465748, COSV99319985; called by muse, mutect2
- GNL1 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770630082, COSV100925397; called by muse, mutect2, varscan2
- GNPNAT1 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 156/172 reads (91%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV99369465; called by muse, mutect2, varscan2
- GOLGB1 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748103063, COSV100511393, COSV61468443; called by muse, mutect2, varscan2
- GPC4 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100895413; called by muse, mutect2, varscan2
- GPRASP2 | c.1218C>G p.I406M | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.556); catalogued as COSV100176584; called by muse, mutect2
- GSDMC | c.608A>C p.K203T | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.284); catalogued as COSV99415658; called by muse, mutect2, varscan2
- GSDMC | c.607A>G p.K203E | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.714); catalogued as COSV99415659; called by muse, mutect2, varscan2
- HACE1 | c.1679-1G>C p.X560_splice | Splice Site (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99493384; called by muse, mutect2, varscan2
- HACL1 | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1024535603, COSV100337152; called by muse, mutect2, varscan2
- HBE1 | c.118C>A p.Q40K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV99496058; called by muse, varscan2
- HCFC1 | c.5981C>T p.A1994V | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100128564; called by muse, mutect2, varscan2
- HECW1 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.024); catalogued as COSV101222967; called by muse, mutect2, varscan2
- HGF | c.709C>T p.H237Y | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.325); catalogued as COSV99735913; called by muse, mutect2, varscan2
- HTR2A | c.288C>G p.I96M | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101096603; called by muse, mutect2, varscan2
- HUWE1 | c.13000C>T p.R4334C | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99470919; called by muse, mutect2, varscan2
- IMPG2 | c.550C>G p.P184A | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV99514961; called by muse, mutect2, varscan2
- KCND1 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs181033799, COSV99501772; called by muse, mutect2
- KCNH8 | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751609797, COSV100108818; called by muse, mutect2, varscan2
- KIAA0513 | c.490G>T p.V164L | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV99260531; called by muse, mutect2, varscan2
- KIFC2 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.307); catalogued as rs771571926, COSV100023609; called by muse, varscan2
- KLF14 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.277); catalogued as rs1554470773, COSV60588539; called by muse, mutect2
- KLF6 | c.736G>C p.E246Q | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51494175, COSV99434932; called by muse, mutect2, varscan2
- LAMA4 | c.4960G>C p.E1654Q (on ENST00000230538 / NM_001105206.3; = p.E1647Q on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as COSV100037749, COSV100039658; called by muse, mutect2, varscan2
- LCN2 | c.460A>C p.K154Q | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.116); catalogued as COSV99478141; called by muse, mutect2, varscan2
- LRRC37A | c.2269C>T p.P757S | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.901); catalogued as COSV100208120; called by mutect2, varscan2
- MAGEC2 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.213); catalogued as COSV99909440; called by muse, mutect2, varscan2
- MAP1B | c.5402C>T p.S1801L | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.343); catalogued as rs368052791; called by muse, mutect2, varscan2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MBOAT7 | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs376939333; called by muse, mutect2, varscan2
- MED11 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99543422; called by muse, mutect2, varscan2
- MMP17 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs771219521, COSV100861872; called by muse, mutect2, varscan2
- MROH9 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV63010231; called by muse, mutect2
- MUC16 | c.37106C>T p.S12369L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.51); catalogued as COSV101198519; called by muse, mutect2, varscan2
- MUC16 | c.30629C>T p.S10210L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs1409544932, COSV101198522, COSV67442346; called by muse, mutect2, varscan2
- MYH8 | c.3984C>T p.A1328= | Splice Region (SNP) | VAF 30/76 reads (39%) | catalogued as COSV101238290; called by muse, mutect2, varscan2
- MYO1F | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100596429; called by muse, varscan2
- NBEAL1 | c.5059G>C p.E1687Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.196); catalogued as COSV101495616, COSV71374560; called by mutect2, varscan2
- NEDD1 | c.1867C>T p.H623Y | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.789); catalogued as COSV57142901; called by muse, mutect2, varscan2
- NEIL1 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 41/61 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as COSV100748504; called by muse, mutect2, varscan2
- NFKBIZ | c.401C>A p.A134D | Missense Mutation (SNP) | VAF 12/203 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV100396950; called by muse, mutect2
- NLRP1 | c.2901G>A p.M967I | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1214557504, COSV52571149, COSV99333213; called by muse, mutect2, varscan2
- NLRP13 | c.2182C>G p.L728V | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.059); catalogued as COSV100738069, COSV61622851; called by muse, mutect2, varscan2
- OR11L1 | c.93C>A p.F31L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as COSV100869392, COSV63313648; called by muse, mutect2, varscan2
- OR5H14 | c.670A>G p.T224A | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.077); catalogued as rs772956847, COSV101454094, COSV101454338; called by muse, mutect2, varscan2
- PAX2 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 34/72 reads (47%) | catalogued as COSV100694998; called by muse, mutect2, varscan2
- PCDH9 | c.766C>T p.Q256* | Nonsense Mutation (SNP) | VAF 26/62 reads (42%) | catalogued as COSV100118894; called by muse, mutect2, varscan2
- PCDHGA12 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.605); catalogued as COSV52750613; called by muse, mutect2, varscan2
- PCGF1 | c.200-2A>G p.X67_splice | Splice Site (SNP) | VAF 18/73 reads (25%) | catalogued as COSV99283209; called by muse, mutect2, varscan2
- PDZD2 | c.4873C>G p.P1625A | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV99224072; called by muse, mutect2, varscan2
- PEX1 | c.2289G>C p.K763N | Missense Mutation (SNP) | VAF 66/259 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs755784540, COSV99951941; called by muse, mutect2, varscan2
- PGBD2 | c.1185G>T p.R395S | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV100251888; called by muse, mutect2, varscan2
- PIP4K2C | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs368437479; called by muse, mutect2, varscan2
- PLXNA1 | c.3115G>C p.E1039Q | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.756); catalogued as COSV99302485; called by muse, mutect2, varscan2
- PRB2 | c.205C>G p.Q69E | Missense Mutation (SNP) | VAF 86/816 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV101231380; called by muse, varscan2
- RAD50 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.214); catalogued as COSV99528694; called by muse, mutect2, varscan2
- RASA2 | c.2429T>G p.I810S | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV99655734; called by muse, mutect2, varscan2
- RBL1 | c.1897C>T p.R633* | Nonsense Mutation (SNP) | VAF 40/133 reads (30%) | catalogued as rs201261568; called by muse, mutect2, varscan2
- RELN | c.1442G>C p.G481A | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100632728; called by muse, mutect2, varscan2
- RPTOR | c.2520G>A p.K840= | Splice Region (SNP) | VAF 37/150 reads (25%) | catalogued as COSV100155399; called by muse, mutect2, varscan2
- RTP1 | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs745627567, COSV56617786; called by muse, mutect2, varscan2
- SCCPDH | c.1024G>A p.G342S | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100829713; called by muse, mutect2, varscan2
- SERPINB1 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.175); catalogued as rs1292161072, COSV101058368; called by muse, mutect2, varscan2
- SERPINB12 | c.1024T>C p.S342P | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99501513; called by muse, mutect2, varscan2
- SLC13A3 | c.853C>G p.L285V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs368814380; called by muse, mutect2, varscan2
- SLC13A5 | c.915G>T p.E305D | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.6); catalogued as COSV99545751; called by muse, mutect2, varscan2
- SLC33A1 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV99053688; called by muse, mutect2, varscan2
- SMAD4 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV61688158; called by muse, mutect2, varscan2
- SMARCA4 | c.3058G>A p.D1020N | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.501); catalogued as COSV100758215, COSV60807493; called by muse, mutect2, varscan2
- SNTG1 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.97); catalogued as rs1450704094, COSV52442716; called by muse, mutect2, varscan2
- SPDEF | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 48/187 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV99762905; called by muse, mutect2, varscan2
- SPRYD3 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100036591; called by muse, mutect2, varscan2
- STARD13 | c.2867C>T p.S956F (on ENST00000336934 / NM_001243476.3; = p.S838F on NM_052851.3) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV99715536; called by muse, mutect2, varscan2
- STAT1 | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 18/41 reads (44%) | catalogued as rs1258563739, COSV100738491; called by muse, mutect2, varscan2
- SVIL | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs1318680879, COSV100881037; called by muse, mutect2, varscan2
- SYAP1 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.518); catalogued as COSV101204913; called by muse, mutect2, varscan2
- SYTL3 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.6); catalogued as rs764282879, COSV99791623; called by muse, mutect2, varscan2
- TAB3 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as rs751794247, COSV99915877; called by muse, mutect2, varscan2
- TCP11L2 | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | catalogued as COSV100135215; called by muse, mutect2, varscan2
- TIGD2 | c.406C>G p.P136A | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV100392289, COSV57647505; called by muse, mutect2, varscan2
- TMEM168 | c.1481G>C p.R494T | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100454523; called by muse, mutect2, varscan2
- TRIM55 | c.1524+2T>G p.X508_splice | Splice Site (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99396569; called by muse, mutect2, varscan2
- TRMT2B | c.598C>G p.Q200E | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as COSV100105224; called by muse, mutect2, varscan2
- TSHZ3 | c.3053T>C p.I1018T | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.95); catalogued as COSV99550835; called by muse, mutect2, varscan2
- TTC23 | c.543G>A p.W181* | Nonsense Mutation (SNP) | VAF 93/161 reads (58%) | catalogued as COSV100018460; called by muse, mutect2, varscan2
- TTC37 | c.480G>A p.W160* | Nonsense Mutation (SNP) | VAF 28/94 reads (30%) | catalogued as COSV100706423; called by muse, mutect2, varscan2
- TTN | c.59788G>A p.D19930N (on ENST00000591111; = p.D12506N on NM_003319.4) | Missense Mutation (SNP) | VAF 23/63 reads (37%) | PolyPhen benign (0.098); catalogued as rs750771623, COSV100598479; called by muse, mutect2, varscan2
- TUBG2 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs952187413, COSV99257353; called by mutect2, varscan2
- TUT4 | c.3655G>C p.E1219Q | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); catalogued as COSV99931915; called by muse, mutect2, varscan2
- VPS13A | c.5762G>A p.R1921Q | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs145524733; called by muse, mutect2, varscan2
- XRCC4 | c.422A>C p.N141T | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as COSV99982196; called by muse, mutect2, varscan2
- XXYLT1 | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as rs1421122625, COSV100118151; called by muse, mutect2, varscan2
- ZBBX | c.1235C>G p.P412R | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV100283275; called by muse, mutect2, varscan2
- ZNF184 | c.1990C>T p.H664Y | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99279438; called by muse, mutect2, varscan2
- ZNF184 | c.1460C>T p.S487L | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV99279443; called by muse, mutect2, varscan2
- ZNF528 | c.1382G>A p.G461E | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV100846622; called by muse, mutect2, varscan2
- ZNF667 | c.259G>T p.G87W | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV99410109; called by muse, mutect2, varscan2
- ADRA2C | c.566C>G p.S189W | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ANKRD30A | c.2565del p.I856Ffs*6 (on ENST00000611781; = p.I800Ffs*6 on NM_052997.2) | Frame Shift Del (DEL) | VAF 10/79 reads (13%) | called by mutect2, pindel, varscan2
- ARHGEF10 | c.3740_3749del p.A1247Vfs*8 (on ENST00000398564; = p.A1222Vfs*8 on NM_014629.4) | Frame Shift Del (DEL) | VAF 15/84 reads (18%) | called by mutect2, pindel, varscan2
- CAMKV | c.406_412del p.L136Hfs*20 | Frame Shift Del (DEL) | VAF 8/53 reads (15%) | called by mutect2, pindel, varscan2
- CASZ1 | c.1514_1526del p.K505Tfs*60 | Frame Shift Del (DEL) | VAF 21/54 reads (39%) | called by mutect2, pindel, varscan2
- DNAH2 | c.12219del p.F4075Sfs*87 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | called by mutect2, pindel, varscan2
- GALNT5 | c.592del p.R198Gfs*13 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by mutect2, pindel, varscan2
- MUC3A | c.7181C>A p.S2394* | Nonsense Mutation (SNP) | VAF 81/291 reads (28%) | called by muse, mutect2, varscan2
- NCKAP5 | c.1380del p.C461Afs*12 | Frame Shift Del (DEL) | VAF 13/65 reads (20%) | called by mutect2, pindel, varscan2
- PRR14 | c.565A>G p.I189V | Missense Mutation (SNP) | VAF 17/317 reads (5%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2
- TNIK | c.3815_3824del p.T1272Rfs*20 | Frame Shift Del (DEL) | VAF 14/129 reads (11%) | called by mutect2, pindel, varscan2
- ABCA3 | c.60G>A p.R20= | Silent (SNP) | VAF 46/73 reads (63%) | catalogued as COSV100068118; called by muse, mutect2, varscan2
- ADGRV1 | c.3075C>T p.L1025= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV101315568; called by muse, mutect2, varscan2
- AP4M1 | c.1257C>G p.L419= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV100384730; called by muse, mutect2, varscan2
- BTBD7 | c.2880C>T p.L960= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs769633347, COSV100597572; called by muse, mutect2, varscan2
- CCIN | c.210C>T p.I70= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100631744; called by muse, mutect2, varscan2
- CDH16 | c.1899G>C p.T633= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100233693; called by muse, mutect2, varscan2
- CEACAM5 | c.1092G>A p.P364= | Silent (SNP) | VAF 31/205 reads (15%) | catalogued as rs149933160; called by muse, mutect2, varscan2
- CLCA2 | c.2289G>T p.V763= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as COSV100991403; called by muse, mutect2, varscan2
- CLEC4F | c.105G>A p.P35= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs370268756; called by muse, mutect2, varscan2
- DBF4B | c.33C>T p.L11= | Silent (SNP) | VAF 113/379 reads (30%) | catalogued as COSV100154328; called by muse, mutect2, varscan2
- DIO2 | c.450C>T p.F150= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV101375826; called by muse, mutect2, varscan2
- DRC3 | c.360G>A p.R120= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV100572639, COSV100572819; called by muse, mutect2
- DZIP1L | c.555C>A p.I185= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100551167; called by muse, mutect2, varscan2
- EBF1 | c.1308G>A p.V436= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV58196522; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1692C>T p.F564= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as rs1433122404, COSV62568492, COSV62568976; called by muse, mutect2, varscan2
- F5 | c.921C>T p.I307= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV63121259; called by muse, mutect2, varscan2
- FCGBP | c.12597C>T p.F4199= | Silent (SNP) | VAF 13/79 reads (16%) | called by muse, mutect2, varscan2
- FGG | c.567G>A p.Q189= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV100271732; called by muse, mutect2, varscan2
- FSIP2 | c.18456G>A p.K6152= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs752196195, COSV100554292; called by muse, mutect2, varscan2
- FZD8 | c.879C>T p.F293= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV101020192; called by muse, mutect2, varscan2
- GALNT5 | c.969G>C p.V323= | Silent (SNP) | VAF 30/105 reads (29%) | catalogued as COSV99374912; called by muse, mutect2, varscan2
- GATA1 | c.402G>A p.E134= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV100936721, COSV100936839; called by muse, mutect2, varscan2
- GPC3 | c.1314G>A p.R438= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV63664812; called by muse, mutect2, varscan2
- GPR65 | c.279C>T p.L93= | Silent (SNP) | VAF 55/159 reads (35%) | catalogued as rs1567030558, COSV99965944; called by muse, mutect2, varscan2
- GRIK5 | c.1893C>T p.I631= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV99490134; called by muse, mutect2, varscan2
- HCN1 | c.1371G>A p.L457= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV57491077, COSV57497442, COSV57503513; called by muse, mutect2, varscan2
- IRGC | c.129C>A p.L43= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as COSV99746106; called by muse, mutect2, varscan2
- ITM2A | c.696C>T p.L232= | Silent (SNP) | VAF 34/61 reads (56%) | catalogued as COSV100964418; called by muse, mutect2, varscan2
- KBTBD12 | c.1053G>A p.K351= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as COSV100675355; called by muse, mutect2, varscan2
- LILRA5 | c.729C>G p.L243= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV100006786; called by muse, mutect2, varscan2
- LRRTM1 | c.9C>T p.F3= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs1346511887, COSV54440359; called by muse, mutect2, varscan2
- LSG1 | c.1806G>C p.V602= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV99503051; called by muse, mutect2, varscan2
- MARK4 | c.546G>A p.L182= | Silent (SNP) | VAF 68/153 reads (44%) | catalogued as COSV99487958; called by muse, mutect2, varscan2
- MGA | c.3609C>T p.L1203= | Silent (SNP) | VAF 48/185 reads (26%) | catalogued as COSV99578843; called by muse, mutect2, varscan2
- MMP8 | c.285C>T p.D95= | Silent (SNP) | VAF 28/51 reads (55%) | catalogued as rs1233974219, COSV99368247; called by muse, mutect2, varscan2
- NLRC3 | c.465G>A p.V155= | Silent (SNP) | VAF 38/54 reads (70%) | catalogued as COSV57092278; called by muse, mutect2, varscan2
- NR1I2 | c.225G>A p.L75= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs766547239, COSV61977260, COSV61979732; called by muse, mutect2, varscan2
- OR5D16 | c.441G>A p.V147= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV101003864; called by muse, mutect2
- PCDHGA4 | c.687C>T p.R229= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV99532727; called by muse, mutect2, varscan2
- PKM | c.312C>T p.L104= | Silent (SNP) | VAF 61/107 reads (57%) | catalogued as rs779591275, COSV100064569; called by muse, mutect2, varscan2
- PSD2 | c.474C>T p.L158= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as rs746655064, COSV99217038; called by muse, mutect2, varscan2
- PTPRO | c.3420G>A p.V1140= (on ENST00000281171 / NM_030667.3; = p.V1112= on NM_002848.4) | Silent (SNP) | VAF 43/158 reads (27%) | catalogued as COSV99839938; called by muse, mutect2, varscan2
- SHARPIN | c.774C>T p.F258= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV100010254; called by muse, mutect2, varscan2
- SLC4A4 | c.2199C>T p.I733= (on ENST00000264485 / NM_001098484.3; = p.I689= on NM_003759.4) | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV52639137; called by muse, mutect2, varscan2
- SLC6A1 | c.306C>T p.C102= | Silent (SNP) | VAF 49/149 reads (33%) | catalogued as rs755042094, COSV99822486; called by muse, mutect2, varscan2
- SPRY4 | c.24C>T p.S8= (on ENST00000434127 / NM_001127496.3; = p.S31= on NM_030964.4) | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs934333789, COSV100702147; called by muse, mutect2, varscan2
- TBC1D10A | c.123C>T p.L41= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs775782497, COSV53164008; called by muse, mutect2, varscan2
- TENM2 | c.4326G>A p.E1442= (on ENST00000518659 / NM_001122679.2; = p.E1203= on NM_001080428.3) | Silent (SNP) | VAF 45/167 reads (27%) | catalogued as rs1405697690, COSV101318087; called by muse, mutect2, varscan2
- TMC8 | c.1722G>A p.V574= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as COSV100573686, COSV100573770; called by muse, mutect2, varscan2
- TOR3A | c.825C>T p.L275= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as rs756375141, COSV100751248; called by muse, mutect2, varscan2
- TRGV3 | c.243C>G p.L81= | Silent (SNP) | VAF 29/111 reads (26%) | called by muse, mutect2, varscan2
- TRIB3 | c.540G>A p.L180= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99423657; called by muse, mutect2, varscan2
- TRIO | c.3021C>G p.L1007= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as rs756381004, COSV100710011; called by muse, mutect2
- UMODL1 | c.3594C>T p.F1198= (on ENST00000408910 / NM_001004416.2; = p.F1326= on NM_173568.3) | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs1375900383, COSV101252495; called by muse, mutect2, varscan2
- USP14 | c.936C>T p.I312= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV99863858; called by muse, varscan2
- ZNF71 | c.774C>T p.I258= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs780467724, COSV100045678, COSV60147515; called by muse, mutect2, varscan2
- DIP2C | c.3924+2044T>C | Intron (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- GRB2 | c.-2G>A | 5'UTR (SNP) | VAF 37/141 reads (26%) | catalogued as COSV57307290; called by muse, mutect2, varscan2
- HOMER3 | c.*174T>A | 3'UTR (SNP) | VAF 15/74 reads (20%) | catalogued as COSV99650955; called by muse, mutect2, varscan2
- OR52A4P | n.756G>A | RNA (SNP) | VAF 20/69 reads (29%) | called by muse, mutect2, varscan2
- TMEM167B | chr1:109100386 G>A | 3'Flank (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
